Somatic mutation profile of tumor specimen TCGA-53-7624-01A (aliquot TCGA-53-7624-01A-11D-2063-08) from TCGA case TCGA-53-7624, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 40.5 years (14,794 days).
Specimen TCGA-53-7624-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) baa26760-7f80-4254-bb9d-ce5b8a3e320f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-53-7624-10A (Blood Derived Normal), aliquot TCGA-53-7624-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/327fe3d9-a1ba-413e-b37c-b07fc3ca2382

The open-access MAF lists 867 somatic variants for this specimen: 663 protein-altering or splice-affecting, 187 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 576, Silent 187, Nonsense Mutation 42, Splice Site 17, Frame Shift Del 14, RNA 7, Frame Shift Ins 7, Intron 6, Splice Region 5, 5'Flank 2, 5'UTR 1, Nonstop Mutation 1.

Variants (750 of 867; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC2H1 | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as rs371011047, CM133140, COSV62085201; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRIN2B | c.2360-2A>G p.X787_splice | Splice Site (SNP) | VAF 16/48 reads (33%) | catalogued as rs1057519612, CS107229, COSV74207605, COSV74208426; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.993+1G>T p.X331_splice | Splice Site (SNP) | VAF 34/48 reads (71%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1690G>T p.E564* (on ENST00000272895 / NM_173076.3; = p.E246* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV55980109; called by muse, mutect2
- ABCD2 | c.1700T>A p.V567E | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV58055797; called by muse, mutect2, varscan2
- ACAD10 | c.2392C>G p.Q798E | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV58164635; called by muse, mutect2, varscan2
- ACSL6 | c.109G>T p.A37S (on ENST00000379240; = p.A62S on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV57306836; called by muse, mutect2, varscan2
- ACVR2A | c.1348-1G>C p.X450_splice | Splice Site (SNP) | VAF 36/59 reads (61%) | catalogued as COSV54030211; called by muse, mutect2, varscan2
- ADAMTS1 | c.2143G>T p.G715C | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53174291; called by muse, mutect2, varscan2
- ADAMTS12 | c.2294A>G p.Y765C | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61283979; called by muse, mutect2, varscan2
- ADAMTS16 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV57010300; called by muse, mutect2, varscan2
- ADAMTS20 | c.5252C>T p.P1751L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67141453; called by muse, mutect2, varscan2
- ADCY10 | c.316A>T p.R106W | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs985668365, COSV63245915; called by muse, mutect2, varscan2
- ADGRB3 | c.4009C>G p.H1337D | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV53233457, COSV53263338, COSV53263707; called by muse, mutect2, varscan2
- ADGRL4 | c.1651C>A p.L551I | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.257); catalogued as COSV66067118; called by muse, mutect2, varscan2
- ADGRV1 | c.6371C>A p.A2124E | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV67997121; called by muse, mutect2, varscan2
- ADH1B | c.998T>C p.V333A | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV59299352; called by muse, mutect2, varscan2
- ADH1B | c.568-2A>T p.X190_splice | Splice Site (SNP) | VAF 32/162 reads (20%) | catalogued as COSV59295766; called by muse, mutect2, varscan2
- ADH6 | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52954866, COSV52958569; called by muse, mutect2, varscan2
- AFF2 | c.2162A>T p.N721I | Missense Mutation (SNP) | VAF 102/145 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV54011448; called by muse, mutect2, varscan2
- AFF2 | c.3524A>T p.K1175M | Missense Mutation (SNP) | VAF 101/128 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV54011466; called by muse, mutect2, varscan2
- AFM | c.1046C>A p.T349N | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV56922774; called by muse, mutect2, varscan2
- AHNAK | c.9692C>T p.P3231L | Missense Mutation (SNP) | VAF 95/218 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs371833005, COSV57215275; called by muse, mutect2, varscan2
- AKAP1 | c.2223G>T p.Q741H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV61807394; called by muse, mutect2, varscan2
- ALDH1A1 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as rs190750432, COSV52795220; called by muse, mutect2, varscan2
- AMER1 | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV57669742; called by muse, mutect2, varscan2
- AMZ1 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs770980663, COSV56689503; called by muse, mutect2
- ANGPT4 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs557880338, COSV67920719; called by muse, mutect2, varscan2
- ANKRD45 | c.464A>T p.Q155L | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV60962870; called by muse, mutect2, varscan2
- ANLN | c.2163G>T p.Q721H | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as COSV56080332; called by muse, mutect2, varscan2
- APOB | c.1979T>C p.I660T | Missense Mutation (SNP) | VAF 104/181 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs200533347, COSV51957746; called by muse, mutect2, varscan2
- APPL1 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV55704207; called by muse, mutect2, varscan2
- ARAP2 | c.4286-1G>T p.X1429_splice | Splice Site (SNP) | VAF 54/162 reads (33%) | catalogued as COSV58285380, COSV58294003; called by muse, varscan2
- AREL1 | c.1489G>T p.D497Y | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV62666254; called by muse, mutect2, varscan2
- ARHGAP19 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755467381, COSV57395116; called by muse, mutect2, varscan2
- ARHGAP21 | c.5476G>T p.G1826W | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs370251256, COSV57603623; called by muse, mutect2, varscan2
- ARL4D | c.232G>T p.G78W | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60722032; called by muse, mutect2, varscan2
- ARSB | c.857G>A p.S286N | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53730527; called by muse, mutect2, varscan2
- ASCC1 | c.493C>G p.L165V (on ENST00000342444 / NM_001369085.1; = p.L137V on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.794); catalogued as COSV57729743; called by muse, mutect2, varscan2
- ASIC3 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as COSV52511699; called by muse, mutect2, varscan2
- ASNS | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51556827; called by muse, mutect2, varscan2
- ASNSD1 | c.493G>T p.G165* | Nonsense Mutation (SNP) | VAF 47/171 reads (27%) | catalogued as COSV53625499; called by muse, mutect2, varscan2
- ATAD3B | c.397G>T p.A133S (on ENST00000308647; = p.A239S on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/103 reads (72%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV58019000, COSV58023681; called by muse, mutect2, varscan2
- ATF7 | c.435G>T p.K145N (on ENST00000548446 / NM_001366555.2; = p.K134N on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV60646988; called by mutect2, varscan2
- ATG2B | c.5256G>C p.L1752F | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV55892486; called by muse, mutect2, varscan2
- ATG2B | c.326-1G>T p.X109_splice | Splice Site (SNP) | VAF 12/26 reads (46%) | catalogued as COSV63426389; called by muse, mutect2, varscan2
- ATG4A | c.755A>T p.Q252L | Missense Mutation (SNP) | VAF 106/157 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV58967959; called by muse, mutect2, varscan2
- ATM | c.1688T>C p.M563T | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV53781950; called by muse, mutect2, varscan2
- ATP1A4 | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV100927587, COSV63629013; called by muse, mutect2, varscan2
- ATP2A2 | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57876553; called by muse, mutect2, varscan2
- ATP8B4 | c.2386G>T p.A796S | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV52718930; called by muse, mutect2, varscan2
- B4GALNT4 | c.1096G>T p.V366L | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV100327695, COSV57327221; called by muse, mutect2, varscan2
- BAALC | c.290C>A p.S97Y (on ENST00000297574 / NM_001364874.1; = p.S62Y on NM_024812.3) | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV52565797; called by muse, mutect2, varscan2
- BACH2 | c.2321C>A p.A774E | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV57612203; called by muse, mutect2, varscan2
- BAZ2A | c.1492G>T p.V498L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV51635101, COSV99464559; called by muse, mutect2
- BCAR1 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs758457850, COSV50810745; called by muse, mutect2
- BCL11A | c.1675G>T p.E559* (on ENST00000335712 / NM_001365609.1; = p.E593* on NM_018014.4) | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as COSV59639033; called by muse, mutect2, varscan2
- BICRAL | c.862C>G p.Q288E | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); catalogued as COSV58406551; called by muse, mutect2, varscan2
- BICRAL | c.1442C>G p.S481C | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as COSV58409035; called by muse, mutect2, varscan2
- BIRC6 | c.12985A>T p.S4329C | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70207682; called by muse, mutect2, varscan2
- BMP7 | c.865C>G p.R289G | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV67783177; called by muse, mutect2, varscan2
- BMS1 | c.2201G>T p.C734F | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.467); catalogued as COSV100996769, COSV65735863; called by muse, mutect2, varscan2
- BRAP | c.121C>G p.L41V | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs1299353030, COSV58164608; called by muse, mutect2, varscan2
- BRDT | c.2410G>A p.D804N | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.521); catalogued as COSV62868217; called by muse, mutect2, varscan2
- BRINP3 | c.637G>T p.G213C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66523548, COSV66544308; called by muse, mutect2, varscan2
- BRWD1 | c.6758C>G p.S2253* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV59001613; called by muse, mutect2, varscan2
- BRWD3 | c.4469G>T p.R1490M | Missense Mutation (SNP) | VAF 58/86 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV64754589; called by muse, mutect2, varscan2
- C10orf120 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.728); catalogued as COSV61492883; called by muse, mutect2, varscan2
- C10orf71 | c.2011G>T p.G671W | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV60514853; called by muse, mutect2, varscan2
- C14orf39 | c.1619A>G p.D540G | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV58785818; called by muse, mutect2, varscan2
- C16orf46 | c.664_665insC p.L222Sfs*6 | Frame Shift Ins (INS) | VAF 34/197 reads (17%) | catalogued as COSV100215072; called by mutect2, pindel, varscan2
- C1orf226 | c.764G>T p.R255L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV63396055, COSV63397301; called by muse, mutect2, varscan2
- C2CD5 | c.2347G>T p.E783* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV61728637; called by muse, mutect2, varscan2
- C6 | c.1120G>C p.V374L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as COSV54710168, COSV54721144; called by muse, mutect2, varscan2
- CABS1 | c.302G>C p.G101A | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.495); catalogued as rs1306000781, COSV56734871; called by muse, mutect2, varscan2
- CACNA1B | c.4554C>G p.C1518W | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53150964, COSV53153369; called by muse, mutect2, varscan2
- CACNG5 | c.488G>T p.R163M | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50061188; called by muse, mutect2, varscan2
- CAD | c.1386G>C p.Q462H | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV53033043; called by muse, mutect2, varscan2
- CAD | c.1539G>T p.E513D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV53033051; called by muse, mutect2, varscan2
- CADPS | c.1204-1G>T p.X402_splice | Splice Site (SNP) | VAF 41/63 reads (65%) | catalogued as COSV51908951; called by muse, mutect2, varscan2
- CAPN13 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.049); catalogued as rs866317100, COSV54436498; called by muse, mutect2, varscan2
- CARD6 | c.1620G>C p.W540C | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV54565237, COSV54569933; called by muse, mutect2, varscan2
- CARMIL2 | c.1472A>G p.H491R | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV58033184; called by muse, mutect2
- CASP4 | c.928A>T p.N310Y | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV67744993; called by muse, mutect2, varscan2
- CBLIF | c.848T>G p.V283G | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57240841; called by muse, mutect2, varscan2
- CBY2 | c.1172G>T p.R391M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60120216; called by muse, mutect2
- CCAR1 | c.1268A>T p.H423L | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56275567; called by muse, mutect2, varscan2
- CCDC170 | c.1969G>T p.V657L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV53347491; called by muse, mutect2, varscan2
- CCDC88A | c.4628A>C p.N1543T (on ENST00000436346 / NM_001365480.1; = p.N1515T on NM_018084.5) | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.15); catalogued as COSV55071652, COSV99711352; called by muse, mutect2, varscan2
- CCKBR | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58098837, COSV58106899; called by muse, mutect2, varscan2
- CCRL2 | c.536A>T p.Y179F | Missense Mutation (SNP) | VAF 53/85 reads (62%) | SIFT tolerated (0.69); PolyPhen benign (0.026); catalogued as COSV62194241; called by muse, mutect2, varscan2
- CCT6A | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV51906536; called by muse, mutect2
- CCT6B | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58492493; called by muse, mutect2
- CD34 | c.717G>T p.R239S | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV60415655; called by muse, mutect2, varscan2
- CDC14A | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as rs375533263, COSV60564808; called by muse, mutect2, varscan2
- CDH10 | c.1778G>A p.G593D | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV52602375; called by muse, mutect2, varscan2
- CDH16 | c.1399A>T p.T467S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV55340364; called by muse, mutect2, varscan2
- CDH18 | c.10A>T p.T4S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV56970714; called by muse, mutect2, varscan2
- CDYL | c.676G>T p.G226C (on ENST00000328908 / NM_001368125.1; = p.G172C on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV59362378; called by muse, mutect2, varscan2
- CECR2 | c.4165G>T p.A1389S (on ENST00000342247 / NM_001290047.2; = p.A1205S on NM_001290046.1) | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV52840275, COSV52850464; called by muse, mutect2, varscan2
- CEMIP | c.1834T>A p.C612S | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55001758; called by muse, mutect2, varscan2
- CEP135 | c.200T>A p.V67D | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV57263459; called by muse, mutect2, varscan2
- CFAP251 | c.2983G>A p.G995S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV56614858; called by muse, mutect2, varscan2
- CHD5 | c.5435T>A p.L1812Q | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV52427606; called by muse, mutect2, varscan2
- CHD7 | c.1072G>T p.G358C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); catalogued as rs745778752, COSV71112466; called by muse, mutect2, varscan2
- CHL1 | c.727G>A p.E243K (on ENST00000397491 / NM_001253387.1; = p.E259K on NM_006614.4) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.186); catalogued as rs200396404, COSV56610063; called by muse, mutect2, varscan2
- CHRM1 | c.471G>T p.W157C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61008134; called by muse, mutect2, varscan2
- CIART | c.938C>A p.P313Q | Missense Mutation (SNP) | VAF 90/196 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV51746535; called by muse, mutect2, varscan2
- CLCA4 | c.970A>G p.N324D | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.104); catalogued as COSV55371850; called by muse, mutect2, varscan2
- CLCN3 | c.1094C>A p.S365Y | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.093); catalogued as COSV61628954; called by muse, mutect2, varscan2
- CLCNKA | c.1278C>A p.F426L | Missense Mutation (SNP) | VAF 102/210 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58894607; called by muse, mutect2, varscan2
- CLEC12B | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as COSV58864764; called by muse, mutect2
- CLEC16A | c.1609C>T p.H537Y | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as COSV68502518; called by muse, mutect2
- CLK1 | c.1118A>G p.Y373C | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1040082581, COSV58436581; called by muse, mutect2, varscan2
- CNBD1 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as COSV72976860; called by muse, mutect2, varscan2
- COBL | c.2294G>T p.G765V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99471067; called by muse, mutect2, varscan2
- COL12A1 | c.3873G>T p.R1291S | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV59411235; called by muse, mutect2, varscan2
- COL28A1 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68085418; called by muse, mutect2, varscan2
- COL3A1 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV58598325; called by muse, mutect2, varscan2
- COL5A1 | c.2822C>T p.P941L | Missense Mutation (SNP) | VAF 66/95 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65676453; called by muse, mutect2, varscan2
- COL6A3 | c.4193C>T p.P1398L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1260592433, COSV55115188; called by muse, mutect2, varscan2
- COL6A3 | c.1624G>A p.G542S | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs756045079, COSV55095820; called by muse, mutect2, varscan2
- COPB2 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100300428; called by muse, mutect2
- CORO2B | c.847C>A p.H283N | Missense Mutation (SNP) | VAF 90/211 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV55958811; called by muse, mutect2, varscan2
- COTL1 | c.188G>C p.R63P | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs755533045, COSV52292082; called by muse, mutect2, varscan2
- CPA6 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1249261686, COSV52745155, COSV99913012; called by muse, mutect2, varscan2
- CPAMD8 | c.1936G>T p.G646W (on ENST00000651564; = p.G599W on NM_015692.5) | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52241539; called by muse, mutect2, varscan2
- CPNE5 | c.648C>G p.H216Q | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV55200942; called by muse, mutect2, varscan2
- CPS1 | c.780G>C p.L260F | Missense Mutation (SNP) | VAF 59/267 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51801653, COSV51807527, COSV51827830; called by muse, mutect2, varscan2
- CR1L | c.775C>A p.Q259K | Missense Mutation (SNP) | VAF 83/247 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.241); catalogued as COSV54332571; called by muse, mutect2, varscan2
- CR2 | c.2852C>A p.P951H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65510265; called by muse, mutect2, varscan2
- CROCC | c.3554G>A p.R1185H | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs542063549, COSV65015436; called by muse, mutect2, varscan2
- CRPPA | c.901C>G p.L301V (on ENST00000407010 / NM_001368197.1; = p.L251V on NM_001101417.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV67909462; called by muse, mutect2, varscan2
- CSMD3 | c.5470C>T p.Q1824* (on ENST00000297405 / NM_001363185.1; = p.Q1720* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 72/127 reads (57%) | catalogued as COSV52294049, COSV52350570; called by muse, mutect2, varscan2
- CSMD3 | c.5303G>T p.G1768V (on ENST00000297405 / NM_001363185.1; = p.G1664V on NM_052900.3) | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52100121; called by muse, mutect2, varscan2
- CSMD3 | c.674C>A p.T225K | Missense Mutation (SNP) | VAF 71/107 reads (66%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.597); catalogued as COSV52313613, COSV52350599; called by muse, mutect2, varscan2
- CTAG2 | c.542G>C p.G181A | Missense Mutation (SNP) | VAF 64/96 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); catalogued as COSV55994300, COSV55997074; called by muse, mutect2, varscan2
- CTNNA2 | c.990G>T p.R330S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1262697787, COSV63586644; called by muse, mutect2, varscan2
- CWF19L2 | c.1820A>T p.K607M | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV56521951; called by muse, mutect2, varscan2
- CYP2C9 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 89/177 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV53254031; called by muse, mutect2, varscan2
- CYP4B1 | c.841A>T p.R281W | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99596741; called by muse, mutect2, varscan2
- DAXX | c.1763C>A p.S588Y | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56469262, COSV56473551; called by muse, mutect2, varscan2
- DBH | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT tolerated (0.45); PolyPhen benign (0.06); catalogued as COSV55042661; called by muse, mutect2, varscan2
- DCLK1 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs146043148, COSV55216921; called by muse, mutect2, varscan2
- DDHD1 | c.1061A>T p.N354I (on ENST00000323669; = p.N551I on NM_030637.3) | Missense Mutation (SNP) | VAF 101/145 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV60363471; called by muse, mutect2, varscan2
- DDX43 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.133); catalogued as COSV64836615; called by muse, mutect2, varscan2
- DDX43 | c.1696C>T p.R566W | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.567); catalogued as rs142525774; called by muse, mutect2, varscan2
- DENND3 | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV52807975; called by muse, mutect2, varscan2
- DENND4B | c.3346G>A p.G1116S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.878); catalogued as COSV63412495; called by muse, mutect2, varscan2
- DEPTOR | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV53823237; called by muse, mutect2, varscan2
- DMBT1 | c.2968A>T p.S990C (on ENST00000338354 / NM_001377530.1; = p.S491C on NM_004406.3) | Missense Mutation (SNP) | VAF 171/462 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV57567850; called by muse, mutect2, varscan2
- DMTN | c.830A>G p.H277R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs761441380, COSV56114458; called by muse, mutect2, varscan2
- DNAH11 | c.7190G>T p.S2397I | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as COSV60948788, COSV60971663; called by muse, mutect2, varscan2
- DNAH9 | c.9757G>T p.E3253* | Nonsense Mutation (SNP) | VAF 70/101 reads (69%) | catalogued as COSV52354999, COSV52382486; called by muse, mutect2, varscan2
- DNER | c.1394G>T p.C465F | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59179357; called by muse, mutect2
- DOCK10 | c.2801C>T p.A934V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs1035653608, COSV51431283; called by muse, mutect2, varscan2
- DPYS | c.1498C>A p.L500M | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as rs981283879, COSV60914557; called by muse, mutect2, varscan2
- DPYSL4 | c.1010C>A p.T337N | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.79); PolyPhen benign (0.405); catalogued as COSV58310443; called by muse, mutect2, varscan2
- DRP2 | c.2201A>G p.Q734R | Missense Mutation (SNP) | VAF 76/125 reads (61%) | SIFT tolerated (0.83); PolyPhen benign (0.011); catalogued as COSV65812193; called by muse, mutect2, varscan2
- DSCAM | c.2205G>T p.Q735H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.482); catalogued as COSV68038717; called by muse, mutect2, varscan2
- DSCAM | c.751C>G p.H251D | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.296); catalogued as COSV68038722; called by muse, mutect2, varscan2
- DTNB | c.1774G>C p.A592P | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56486391; called by muse, mutect2, varscan2
- EIF1AD | c.452A>T p.Q151L | Missense Mutation (SNP) | VAF 112/306 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV56464332; called by muse, mutect2, varscan2
- EIF2AK4 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV55475290; called by muse, mutect2
- ELMO3 | c.1286G>A p.R429K (on ENST00000652269; = p.R376K on NM_024712.5) | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV62608031; called by muse, mutect2, varscan2
- EML2 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV55604921; called by muse, mutect2, varscan2
- EML5 | c.2305G>T p.G769C | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV61352872; called by muse, mutect2, varscan2
- ENPP1 | c.1207C>G p.L403V | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV62937329; called by muse, mutect2, varscan2
- EPAS1 | c.1637G>T p.C546F | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.933); catalogued as COSV55391166; called by muse, mutect2, varscan2
- EPB41L5 | c.1103A>G p.E368G | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55359323; called by muse, mutect2, varscan2
- EPG5 | c.6904G>T p.G2302W | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56357448; called by muse, mutect2, varscan2
- EPPK1 | c.4720G>T p.A1574S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73262499; called by muse, mutect2, varscan2
- EPRS1 | c.2735G>T p.G912V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100859289; called by muse, mutect2, varscan2
- ERAS | c.308G>T p.R103M | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV99504741; called by muse, mutect2, varscan2
- ERBB4 | c.1603T>A p.S535T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV53601213; called by muse, mutect2, varscan2
- ERICH6 | c.1979A>G p.N660S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV55803911; called by muse, varscan2
- ERP27 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56764094; called by muse, mutect2, varscan2
- EYA1 | c.1321G>T p.V441L | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV58176385; called by muse, mutect2, varscan2
- F8 | c.1090G>C p.D364H | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as CD0911168, CM088374, COSV64269651, COSV64279864; called by muse, mutect2, varscan2
- FAM120B | c.1879C>A p.Q627K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53009279; called by muse, mutect2, varscan2
- FAM162B | c.181C>A p.H61N | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs778918883, COSV63920968; called by muse, mutect2, varscan2
- FAM186B | c.611C>G p.T204S | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV57724593; called by muse, mutect2, varscan2
- FAM9C | c.179C>G p.T60R | Missense Mutation (SNP) | VAF 81/136 reads (60%) | SIFT tolerated (0.55); PolyPhen benign (0.037); catalogued as rs1219703037, COSV61776128; called by muse, mutect2, varscan2
- FANCM | c.1462A>T p.S488C | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV57508231; called by muse, mutect2, varscan2
- FAT2 | c.9583C>A p.P3195T | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55832023; called by muse, mutect2, varscan2
- FAT2 | c.6895C>A p.Q2299K | Missense Mutation (SNP) | VAF 54/90 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1176992305, COSV55832037; called by muse, mutect2, varscan2
- FBN2 | c.5352A>T p.T1784= | Splice Region (SNP) | VAF 13/41 reads (32%) | catalogued as COSV52551411; called by muse, mutect2, varscan2
- FBN2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0.012); catalogued as COSV52551436; called by muse, mutect2, varscan2
- FBXO31 | c.1609C>T p.L537F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV61151979; called by muse, mutect2, varscan2
- FBXO4 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.09); catalogued as COSV55854658; called by muse, mutect2, varscan2
- FBXO40 | c.1369G>C p.V457L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.051); catalogued as COSV57522691, COSV57528591; called by muse, mutect2, varscan2
- FCGR2B | c.169C>A p.Q57K | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as CM078107, COSV52683600; called by muse, mutect2, varscan2
- FERMT3 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.424); catalogued as COSV54184587; called by muse, mutect2, varscan2
- FERMT3 | c.666G>C p.K222N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54184607; called by muse, mutect2, varscan2
- FGD1 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1162044129, COSV100910761; called by muse, mutect2, varscan2
- FGD4 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as COSV99846732; called by muse, mutect2, varscan2
- FLG2 | c.3782G>T p.G1261V | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV66174564; called by muse, mutect2, varscan2
- FNBP4 | c.1448G>C p.G483A | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as COSV55452983; called by muse, mutect2, varscan2
- FOXF2 | c.1291C>G p.H431D | Missense Mutation (SNP) | VAF 89/128 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV52527581; called by muse, mutect2
- FRMPD1 | c.2545C>G p.Q849E | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV66699248; called by muse, mutect2, varscan2
- FRMPD2 | c.1058A>T p.H353L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV59724788; called by muse, mutect2, varscan2
- FSIP2 | c.20621C>A p.S6874Y | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58103499; called by muse, mutect2, varscan2
- FST | c.126C>A p.C42* | Nonsense Mutation (SNP) | VAF 26/33 reads (79%) | catalogued as COSV56817195; called by muse, mutect2, varscan2
- FZD7 | c.398C>A p.A133E | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV53811826; called by muse, mutect2, varscan2
- FZD8 | c.1790G>A p.G597D | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65968622; called by muse, mutect2, varscan2
- GABRA4 | c.930G>T p.L310F | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV51923230; called by muse, mutect2, varscan2
- GABRA5 | c.216C>G p.I72M | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV59487040; called by muse, mutect2, varscan2
- GBP4 | c.570C>A p.D190E | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as COSV63256463; called by muse, mutect2, varscan2
- GGN | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.363); catalogued as COSV53056879; called by muse, mutect2
- GLCE | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1044389862, COSV55949064; called by muse, mutect2, varscan2
- GLDC | c.858T>A p.S286R | Missense Mutation (SNP) | VAF 57/67 reads (85%) | SIFT tolerated (0.37); PolyPhen benign (0.049); catalogued as COSV58686451; called by muse, mutect2, varscan2
- GLG1 | c.2645G>T p.R882M | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV52676070; called by muse, varscan2
- GLRA3 | c.494T>A p.L165* | Nonsense Mutation (SNP) | VAF 32/44 reads (73%) | catalogued as COSV56872022; called by muse, mutect2, varscan2
- GLRX3 | c.567G>T p.Q189H | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58694989; called by muse, mutect2, varscan2
- GNRHR | c.605T>C p.F202S | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56935179; called by muse, mutect2, varscan2
- GORASP2 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 89/142 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV52204391; called by muse, mutect2, varscan2
- GPD1 | c.734G>C p.G245A | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as COSV56549349; called by muse, mutect2, varscan2
- GPN1 | c.1112G>A p.R371K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV53118221; called by muse, mutect2, varscan2
- GPR101 | c.1348C>A p.H450N | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.818); catalogued as COSV53240791; called by muse, varscan2
- GPR142 | c.949C>A p.H317N | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs767933837, COSV59520730; called by muse, mutect2, varscan2
- GPR143 | c.280G>T p.G94* | Nonsense Mutation (SNP) | VAF 9/10 reads (90%) | catalogued as rs867433259, COSV66633398; called by muse, mutect2, varscan2
- GRID1 | c.764G>T p.W255L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60060401; called by muse, mutect2, varscan2
- GRID2 | c.1995C>A p.I665= | Splice Region (SNP) | VAF 24/80 reads (30%) | catalogued as COSV56284085; called by muse, mutect2, varscan2
- GRIK3 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 80/254 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV66148427; called by muse, mutect2, varscan2
- GRIN2B | c.2360G>T p.G787V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV74208425; called by muse, mutect2
- GRIN3A | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV62459678; called by muse, mutect2, varscan2
- GRM7 | c.1331G>C p.G444A | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV63166874, COSV63177782; called by muse, mutect2, varscan2
- GRN | c.441G>T p.W147C | Missense Mutation (SNP) | VAF 95/137 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50009859; called by muse, mutect2, varscan2
- GTPBP10 | c.879G>A p.M293I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55989301; called by muse, mutect2, varscan2
- GUCY1A2 | c.521G>C p.G174A | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56505820; called by muse, mutect2, varscan2
- H2AC6 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 129/177 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as COSV58415749; called by muse, mutect2, varscan2
- H2BC7 | c.128A>T p.Y43F | Missense Mutation (SNP) | VAF 224/306 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV61911790, COSV61912523; called by muse, mutect2, varscan2
- HAO2 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100377748; called by muse, mutect2, varscan2
- HECW1 | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs1369607620, COSV67841637; called by muse, mutect2, varscan2
- HERC1 | c.8560G>C p.D2854H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as COSV101496629, COSV71250931; called by muse, mutect2
- HERC5 | c.1963-2A>G p.X655_splice | Splice Site (SNP) | VAF 24/104 reads (23%) | catalogued as COSV52046178; called by muse, mutect2, varscan2
- HGSNAT | c.1549A>C p.I517L | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV52819679; called by muse, mutect2, varscan2
- HOXA4 | c.819C>A p.D273E | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV57829504; called by muse, mutect2, varscan2
- HOXD8 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 28/187 reads (15%) | catalogued as COSV57487010; called by muse, mutect2, varscan2
- HRNR | c.2387C>G p.S796C | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV64263750; called by muse, mutect2, varscan2
- HSPA8 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV57087024; called by muse, mutect2, varscan2
- HYAL1 | c.368C>G p.S123* | Nonsense Mutation (SNP) | VAF 37/136 reads (27%) | catalogued as COSV56499723; called by muse, mutect2, varscan2
- HYAL3 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as COSV56499689; called by muse, mutect2, varscan2
- IAH1 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV53012503; called by muse, mutect2, varscan2
- IARS2 | c.856A>G p.I286V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV56965168; called by muse, mutect2, varscan2
- IFT172 | c.4501C>T p.H1501Y | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs1043702763, COSV53140967; called by muse, mutect2, varscan2
- IGDCC3 | c.1795C>A p.Q599K | Missense Mutation (SNP) | VAF 101/217 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.257); catalogued as COSV60080969; called by muse, mutect2, varscan2
- IGFL2 | c.256C>T p.L86F (on ENST00000377693 / NM_001135113.2; = p.L97F on NM_001002915.2) | Missense Mutation (SNP) | VAF 169/285 reads (59%) | SIFT tolerated (0.72); PolyPhen benign (0.021); catalogued as rs762137936, COSV66617623; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs751628118; called by muse, varscan2
- IGKV1-16 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs773100372; called by muse, mutect2, varscan2
- IGKV4-1 | c.203A>T p.Q68L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs772803928; called by muse, varscan2
- IGLV11-55 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV101135349; called by muse, mutect2, varscan2
- IGSF3 | c.905G>T p.C302F | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59600337; called by muse, mutect2, varscan2
- IGSF8 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.217); catalogued as COSV58759456; called by muse, mutect2, varscan2
- IL20 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV65585302; called by muse, mutect2, varscan2
- IL36A | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 86/193 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV52084090; called by muse, mutect2, varscan2
- IL3RA | c.1035C>G p.I345M | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100452219, COSV58430123, COSV58433847; called by muse, mutect2, varscan2
- IL6R | c.232G>T p.G78* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV59820090; called by muse, mutect2, varscan2
- IMPG1 | c.518A>T p.E173V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV100885865; called by muse, mutect2, varscan2
- IMPG1 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.359); catalogued as COSV100885867; called by muse, mutect2, varscan2
- INPP5D | c.1437A>C p.T479= (on ENST00000445964 / NM_001017915.3; = p.T478= on NM_005541.5) | Splice Region (SNP) | VAF 17/37 reads (46%) | catalogued as COSV64041273; called by muse, mutect2
- IPP | c.700C>G p.Q234E | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV63434423; called by muse, mutect2, varscan2
- IQUB | c.2070C>A p.C690* | Nonsense Mutation (SNP) | VAF 71/98 reads (72%) | catalogued as COSV61238835, COSV61243523; called by muse, mutect2, varscan2
- IRAG1 | c.2523A>T p.L841F | Missense Mutation (SNP) | VAF 65/99 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV70213276; called by muse, mutect2, varscan2
- IRS1 | c.3364G>T p.G1122W | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.976); catalogued as COSV59341147; called by muse, mutect2, varscan2
- ITGA5 | c.1825A>T p.N609Y | Missense Mutation (SNP) | VAF 115/274 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53221385; called by muse, mutect2, varscan2
- ITGAE | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 28/88 reads (32%) | catalogued as rs1168265288, COSV53992037, COSV54001582; called by muse, mutect2, varscan2
- ITPR3 | c.5516C>G p.S1839* | Nonsense Mutation (SNP) | VAF 18/78 reads (23%) | catalogued as COSV65415794; called by muse, mutect2, varscan2
- ITSN2 | c.2736G>C p.K912N | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61955027; called by muse, mutect2, varscan2
- JPH3 | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as COSV52475182; called by muse, mutect2, varscan2
- KCNA5 | c.1587C>A p.H529Q | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0.006); catalogued as COSV52909341; called by muse, mutect2, varscan2
- KCNH3 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 137/285 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs1470227025, COSV57793518; called by muse, mutect2, varscan2
- KCNH8 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 85/127 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60477857, COSV60480152; called by muse, mutect2, varscan2
- KCNJ2 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54664422, COSV99696475; called by muse, mutect2, varscan2
- KCNJ5 | c.24del p.M9* | Frame Shift Del (DEL) | VAF 38/133 reads (29%) | catalogued as COSV100610624; called by mutect2, pindel, varscan2
- KCNU1 | c.3259T>A p.S1087T | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.001); catalogued as COSV67760597; called by muse, mutect2, varscan2
- KEAP1 | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50659720; called by muse, mutect2, varscan2
- KIAA1109 | c.2752G>T p.V918L | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52697626; called by muse, mutect2, varscan2
- KIF19 | c.1807C>A p.H603N | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV100739118, COSV63430837; called by muse, mutect2, varscan2
- KLF6 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV51496600; called by muse, mutect2, varscan2
- KLK6 | c.324G>C p.M108I | Missense Mutation (SNP) | VAF 53/63 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV59566984; called by muse, mutect2, varscan2
- KMT2A | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.011); catalogued as COSV63293928; called by muse, mutect2, varscan2
- KMT2A | c.11194G>C p.E3732Q | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63293932; called by muse, mutect2, varscan2
- KMT2A | c.11326G>C p.D3776H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63293939; called by muse, mutect2, varscan2
- KRT31 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 45/84 reads (54%) | catalogued as rs1338333897, COSV52439216; called by muse, mutect2, varscan2
- KRT74 | c.1531A>G p.K511E | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.14); catalogued as COSV59774134; called by muse, mutect2, varscan2
- KRT77 | c.1123C>A p.L375M | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV59241915; called by muse, mutect2, varscan2
- KRT78 | c.1010A>G p.Q337R | Missense Mutation (SNP) | VAF 87/242 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV58854134; called by muse, mutect2, varscan2
- KRTAP10-8 | c.286C>G p.P96A | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as COSV58166491; called by muse, mutect2, varscan2
- KRTAP12-4 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.813); catalogued as COSV59983742; called by muse, mutect2, varscan2
- LAMA2 | c.2957G>T p.W986L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.129); catalogued as COSV70357241; called by muse, mutect2, varscan2
- LAMA5 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53354903, COSV53374974; called by muse, mutect2, varscan2
- LCOR | c.1454A>C p.E485A | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53719441; called by muse, mutect2, varscan2
- LCTL | c.1169del p.G390Dfs*20 | Frame Shift Del (DEL) | VAF 20/163 reads (12%) | catalogued as COSV100328823; called by pindel, varscan2
- LENG8 | c.1903-1G>T p.X635_splice | Splice Site (SNP) | VAF 71/115 reads (62%) | catalogued as COSV58731090; called by muse, mutect2, varscan2
- LGI1 | c.1427C>G p.S476C | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65059625; called by muse, mutect2, varscan2
- LIAS | c.809A>T p.*270Lext*15 (on ENST00000261434 / NM_001363700.2; = p.*373Lext*15 on NM_006859.4) | Nonstop Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV54697739; called by muse, mutect2, varscan2
- LIG1 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 138/258 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99618397; called by muse, mutect2, varscan2
- LIG4 | c.2678G>T p.W893L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407817431, COSV63598353; called by muse, mutect2, varscan2
- LILRA2 | c.226C>A p.P76T | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as COSV52198709, COSV99253332; called by muse, mutect2, varscan2
- LIPE | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs775624639, COSV54926224; called by muse, mutect2, varscan2
- LRP1B | c.12176G>T p.G4059V | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67285629; called by muse, mutect2, varscan2
- LRP1B | c.2993A>G p.D998G | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67285631; called by muse, mutect2, varscan2
- LRRIQ3 | c.803T>A p.L268H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.674); catalogued as rs1305221185, COSV63051385; called by muse, mutect2
- LSS | c.1103A>G p.Y368C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV62703200; called by muse, mutect2, varscan2
- LTN1 | c.3240-1G>T p.X1080_splice | Splice Site (SNP) | VAF 34/58 reads (59%) | catalogued as COSV63735601; called by muse, varscan2
- LVRN | c.1612G>T p.A538S | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV63498389, COSV63498743; called by muse, mutect2, varscan2
- LYSMD2 | c.415G>C p.A139P | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV51057291; called by muse, mutect2, varscan2
- MAGEA12 | c.827G>T p.R276M | Missense Mutation (SNP) | VAF 192/272 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63294978; called by mutect2, varscan2
- MAGEB18 | c.955G>C p.A319P | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.694); catalogued as COSV57465386; called by muse, mutect2, varscan2
- MAGEB2 | c.808C>A p.R270S | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV66782211; called by muse, mutect2, varscan2
- MAN2B2 | c.1036G>T p.D346Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53454675; called by muse, mutect2, varscan2
- MAP2K5 | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51624626; called by muse, mutect2, varscan2
- MAP3K4 | c.2218A>G p.I740V | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs762026224, COSV62340099; called by muse, mutect2, varscan2
- MAP6 | c.30C>A p.C10* | Nonsense Mutation (SNP) | VAF 26/93 reads (28%) | catalogued as COSV59078519; called by muse, mutect2, varscan2
- MAT2B | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as COSV55202058, COSV55202753; called by muse, mutect2, varscan2
- MATN1 | c.1232T>A p.V411E | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65651624; called by muse, mutect2, varscan2
- MAU2 | c.906G>T p.Q302H | Missense Mutation (SNP) | VAF 65/117 reads (56%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.501); catalogued as COSV53238734; called by muse, mutect2, varscan2
- MCF2L2 | c.1305+2_1305+3insA | Splice Region (INS) | VAF 31/116 reads (27%) | catalogued as COSV100191079; called by mutect2, pindel, varscan2
- MDN1 | c.9513G>T p.Q3171H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.339); catalogued as COSV65532393; called by muse, mutect2, varscan2
- MEIS1 | c.1143G>T p.M381I | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV55493654; called by muse, mutect2, varscan2
- MFGE8 | c.294G>T p.L98F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV51558318; called by muse, mutect2, varscan2
- MFSD6 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs376329761; called by muse, mutect2, varscan2
- MGAT4C | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | catalogued as COSV59839096; called by muse, mutect2, varscan2
- MMP21 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0.045); catalogued as COSV64290637; called by muse, mutect2, varscan2
- MMRN2 | c.946C>A p.H316N | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV64401542; called by muse, mutect2, varscan2
- MNDA | c.771A>T p.K257N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63742310; called by muse, mutect2, varscan2
- MOGS | c.613C>G p.L205V | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV52029683; called by muse, mutect2, varscan2
- MRFAP1 | c.228G>C p.E76D | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV57995345; called by muse, mutect2, varscan2
- MRPL42 | c.30G>T p.M10I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62357584; called by muse, mutect2, varscan2
- MTERF2 | c.921G>C p.L307F | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53528692, COSV53528816; called by muse, mutect2, varscan2
- MTSS2 | c.666G>T p.Q222H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV58698286; called by muse, mutect2, varscan2
- MUC13 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 77/298 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV60700351, COSV60701651; called by muse, mutect2
- MUC5AC | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); catalogued as rs770017652, COSV62255785; called by muse, mutect2, varscan2
- MVK | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV57333332; called by muse, mutect2, varscan2
- MYBL1 | c.1031A>G p.E344G | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV72919291; called by muse, mutect2, varscan2
- MYF5 | c.359A>T p.K120M | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57357077; called by muse, mutect2, varscan2
- MYH15 | c.4556-2A>T p.X1519_splice | Splice Site (SNP) | VAF 27/42 reads (64%) | catalogued as COSV56322052; called by muse, mutect2, varscan2
- MYH6 | c.4207G>A p.E1403K | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769398160, COSV62451870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO18B | c.5715G>T p.E1905D | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV59152244; called by muse, mutect2, varscan2
- MYO9A | c.4309A>G p.T1437A | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.005); catalogued as rs773656437, COSV61860365; called by muse, mutect2, varscan2
- MYT1L | c.2282C>A p.P761H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV67735188; called by muse, mutect2, varscan2
- N6AMT1 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV58136189; called by muse, mutect2, varscan2
- NALCN | c.4512C>A p.D1504E | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV51972257; called by muse, mutect2, varscan2
- NAV3 | c.6745G>T p.D2249Y (on ENST00000397909 / NM_001024383.2; = p.D2227Y on NM_014903.6) | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99886526; called by muse, mutect2, varscan2
- NCAM1 | c.1366C>A p.P456T (on ENST00000316851 / NM_181351.5; = p.P446T on NM_000615.7) | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57525078, COSV57527382; called by muse, varscan2
- NCAPD3 | c.3942G>T p.Q1314H | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV73188019; called by muse, mutect2, varscan2
- NDUFB5 | c.359G>T p.W120L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.705); catalogued as COSV52022066; called by muse, mutect2, varscan2
- NEB | c.13723T>G p.W4575G | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51468218; called by muse, mutect2, varscan2
- NEDD4 | c.3955G>T p.D1319Y (on ENST00000508342 / NM_001284338.1; = p.D900Y on NM_006154.4) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59067723; called by muse, mutect2
- NEGR1 | c.595G>T p.G199W | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60843956; called by muse, mutect2, varscan2
- NFATC2IP | c.411C>G p.I137M | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.448); catalogued as COSV57911655; called by muse, mutect2, varscan2
- NFIC | c.986A>T p.E329V | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1044672547, COSV59417833; called by muse, mutect2, varscan2
- NID1 | c.835G>A p.V279M | Missense Mutation (SNP) | VAF 82/317 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs538754279, COSV51630558; called by muse, mutect2, varscan2
- NIT1 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.175); catalogued as rs201355520, COSV63502897; called by muse, mutect2, varscan2
- NKPD1 | c.2053G>C p.E685Q | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.213); catalogued as COSV58728845, COSV58730405; called by muse, mutect2
- NLGN3 | c.1487G>A p.R496H (on ENST00000358741 / NM_181303.2; = p.R476H on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV62445640; called by muse, mutect2, varscan2
- NLRP12 | c.1939C>A p.H647N | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV60757277; called by muse, mutect2, varscan2
- NLRP2 | c.118C>A p.Q40K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.615); catalogued as COSV99671825; called by muse, mutect2, varscan2
- NLRP2 | c.119A>G p.Q40R | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as COSV99671829; called by muse, mutect2, varscan2
- NLRP3 | c.578C>G p.T193R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs76291085, COSV100275148; called by muse, mutect2, varscan2
- NLRP4 | c.2187-1G>T p.X729_splice | Splice Site (SNP) | VAF 68/122 reads (56%) | catalogued as COSV56725393; called by muse, mutect2, varscan2
- NMUR2 | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 65/85 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV54923560; called by muse, mutect2, varscan2
- NR1H4 | c.83A>T p.E28V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as COSV51857977; called by muse, mutect2
- NR5A2 | c.169G>T p.G57W | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as COSV52659398; called by muse, mutect2
- NRROS | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60748272; called by muse, mutect2, varscan2
- NSMAF | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as COSV50704613; called by muse, mutect2, varscan2
- NSUN6 | c.746C>A p.T249K | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1310520815, COSV66035799; called by muse, mutect2, varscan2
- NUDT12 | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV50093611; called by muse, mutect2, varscan2
- NUP205 | c.1226A>T p.Q409L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV53667512; called by muse, mutect2, varscan2
- OGDH | c.2773G>A p.V925M | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV56058524; called by muse, mutect2, varscan2
- OLFM3 | c.1369A>G p.N457D (on ENST00000338858 / NM_001288821.1; = p.N437D on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.989); catalogued as COSV58805817; called by muse, mutect2, varscan2
- OR10A5 | c.548C>A p.P183Q | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV55056072; called by muse, varscan2
- OR10Z1 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 89/267 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV63526119; called by muse, mutect2, varscan2
- OR14C36 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58603214; called by muse, varscan2
- OR2AK2 | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 58/304 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV63547868; called by muse, mutect2, varscan2
- OR2G6 | c.722G>A p.C241Y | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58576198; called by muse, mutect2, varscan2
- OR2T1 | c.867C>A p.Y289* | Nonsense Mutation (SNP) | VAF 39/193 reads (20%) | catalogued as COSV63542350, COSV63543090; called by muse, mutect2, varscan2
- OR2T12 | c.77T>G p.F26C | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV58780104; called by muse, mutect2, varscan2
- OR2T8 | c.856C>A p.L286I | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as rs775335952, COSV60665375; called by muse, varscan2
- OR4A47 | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 60/81 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV71445055, COSV71445218; called by muse, mutect2, varscan2
- OR4D5 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58310096; called by muse, mutect2, varscan2
- OR4E2 | c.377T>C p.I126T | Missense Mutation (SNP) | VAF 101/145 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV57732449; called by muse, mutect2, varscan2
- OR4K2 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 96/296 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs970711474, COSV53852170; called by muse, varscan2
- OR51D1 | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 55/84 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62914979; called by muse, mutect2, varscan2
- OR51E2 | c.115T>A p.F39I | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV67809090; called by muse, mutect2, varscan2
- OR51M1 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as COSV60785807; called by muse, mutect2, varscan2
- OR51V1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV58314939, COSV58316730; called by muse, mutect2
- OR52A5 | c.209C>G p.A70G | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.347); catalogued as COSV56615504, COSV56617184; called by muse, mutect2, varscan2
- OR52I2 | c.403C>A p.H135N | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100442817; called by muse, mutect2, varscan2
- OR56A4 | c.500C>A p.S167Y | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58112162; called by muse, mutect2, varscan2
- OR5M11 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV73142048; called by muse, mutect2, varscan2
- OR5T1 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 81/230 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.074); catalogued as COSV57305305; called by muse, mutect2, varscan2
- OR6C70 | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.17); catalogued as COSV59245561; called by muse, mutect2, varscan2
- OR6Q1 | c.375T>A p.D125E | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56934012, COSV56935050; called by muse, mutect2, varscan2
- OR8H1 | c.191C>T p.T64I | Missense Mutation (SNP) | VAF 138/385 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs1261216660, COSV57293832, COSV57296346; called by muse, mutect2, varscan2
- OR8I2 | c.269G>A p.R90K | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56169224, COSV56171123; called by muse, varscan2
- OSBPL5 | c.2328G>C p.E776D | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.143); catalogued as COSV55146769; called by muse, mutect2, varscan2
- OTOP3 | c.1268G>T p.R423L | Missense Mutation (SNP) | VAF 52/68 reads (76%) | SIFT tolerated (0.3); PolyPhen benign (0.214); catalogued as COSV60915073, COSV60915467; called by muse, mutect2, varscan2
- OTUD7A | c.1957C>T p.R653W (on ENST00000307050 / NM_001382637.1; = p.R646W on NM_130901.3) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61044503; called by muse, mutect2, varscan2
- OTX1 | c.97+1G>T p.X33_splice | Splice Site (SNP) | VAF 49/105 reads (47%) | catalogued as COSV56996501; called by muse, mutect2, varscan2
- OVOL1 | c.760C>G p.Q254E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV60120680; called by muse, mutect2, varscan2
- P2RX1 | c.840C>A p.Y280* | Nonsense Mutation (SNP) | VAF 31/42 reads (74%) | catalogued as rs144076351, COSV56656390; called by muse, mutect2, varscan2
- PACRG | c.40C>G p.P14A | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.04); catalogued as COSV58288655; called by muse, mutect2, varscan2
- PAH | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV61021027, COSV61021233; called by muse, mutect2, varscan2
- PAPPA2 | c.489G>T p.Q163H | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.066); catalogued as COSV62788700; called by muse, mutect2, varscan2
- PAPPA2 | c.3169C>A p.R1057S | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as COSV62814669; called by muse, varscan2
- PAPPA2 | c.4601C>A p.A1534D | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754788575, COSV62814673; called by muse, mutect2, varscan2
- PARD3B | c.1273G>T p.G425C | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62509263, COSV62534755; called by muse, mutect2, varscan2
- PCDH11X | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs748002525, COSV53441785; called by muse, mutect2, varscan2
- PCDH9 | c.3143A>G p.Q1048R (on ENST00000377865 / NM_203487.3; = p.Q1014R on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.05); catalogued as rs770284088, COSV100117998; called by muse, mutect2, varscan2
- PCDH9 | c.3142C>A p.Q1048K (on ENST00000377865 / NM_203487.3; = p.Q1014K on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100118000; called by muse, mutect2, varscan2
- PCDHGA5 | c.1718C>A p.T573K | Missense Mutation (SNP) | VAF 111/159 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.701); catalogued as rs777611384, COSV53898348, COSV53907797, COSV53983144; called by muse, mutect2, varscan2
- PCDHGA6 | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV54055692; called by muse, mutect2, varscan2
- PCDHGA8 | c.1724T>G p.V575G | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV54055718; called by muse, mutect2, varscan2
- PCLO | c.1649C>T p.S550L | Missense Mutation (SNP) | VAF 144/226 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs747807413, COSV61626658; called by muse, mutect2, varscan2
- PCSK5 | c.1008C>A p.S336R | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65098516; called by muse, mutect2, varscan2
- PDE1C | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58532621; called by muse, mutect2, varscan2
- PDE3B | c.1520C>G p.A507G | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as COSV56392347; called by muse, mutect2, varscan2
- PDE6A | c.1489G>T p.D497Y | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV54932713; called by muse, mutect2, varscan2
- PDE6B | c.106T>A p.C36S | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV55332032; called by muse, mutect2, varscan2
- PDE6C | c.1859C>A p.P620Q | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65118140; called by muse, mutect2, varscan2
- PDGFD | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56397623; called by muse, mutect2, varscan2
- PDLIM2 | c.453C>G p.I151M (on ENST00000397760; = p.I401M on NM_021630.6) | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV56134008, COSV56135416; called by muse, mutect2, varscan2
- PGM2L1 | c.1106G>A p.W369* | Nonsense Mutation (SNP) | VAF 29/91 reads (32%) | catalogued as rs1007612452, COSV53350509; called by muse, mutect2, varscan2
- PGM3 | c.311G>C p.R104T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV52286419; called by muse, varscan2
- PHB2 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54644247; called by muse, mutect2, varscan2
- PHF3 | c.2753C>T p.S918F | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV50351335; called by muse, mutect2, varscan2
- PHKA2 | c.1411A>T p.I471F | Missense Mutation (SNP) | VAF 71/121 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.25); catalogued as COSV66056140, COSV66056999; called by muse, mutect2, varscan2
- PHOX2B | c.188del p.G63Dfs*71 | Frame Shift Del (DEL) | VAF 31/111 reads (28%) | catalogued as COSV56928690, COSV56931720; called by mutect2, pindel, varscan2
- PIEZO2 | c.7837G>T p.D2613Y | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs770447224, COSV53290249, COSV53295613; called by muse, mutect2, varscan2
- PIK3R1 | c.610A>T p.S204C | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV57142474; called by muse, mutect2, varscan2
- PJA1 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.998); catalogued as COSV64053733; called by muse, mutect2, varscan2
- PKD1L1 | c.2503G>C p.D835H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV56980861; called by muse, mutect2, varscan2
- PKHD1 | c.4780G>A p.E1594K | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.084); catalogued as rs760267666, COSV61898717; called by muse, varscan2
- PKMYT1 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 10/16 reads (63%) | catalogued as rs894254778, COSV51893082; called by muse, varscan2
- PLA2G6 | c.498G>C p.E166D | Missense Mutation (SNP) | VAF 129/201 reads (64%) | SIFT tolerated (0.16); PolyPhen benign (0.439); catalogued as COSV59274251; called by muse, mutect2, varscan2
- PLCE1 | c.1578G>T p.Q526H | Missense Mutation (SNP) | VAF 85/179 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.347); catalogued as COSV53376546; called by muse, mutect2, varscan2
- PLCH1 | c.3514C>G p.L1172V (on ENST00000340059 / NM_001130960.2; = p.L1164V on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV100396126, COSV58212282; called by muse, mutect2, varscan2
- PLXNB2 | c.4984G>A p.D1662N | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63785110; called by muse, mutect2, varscan2
- POLE | c.4468T>C p.Y1490H | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV57692614; called by muse, mutect2, varscan2
- POMK | c.859G>C p.D287H | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV58858919; called by muse, mutect2, varscan2
- POMP | c.65G>T p.S22I | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV66482257; called by muse, mutect2, varscan2
- PON1 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 59/85 reads (69%) | catalogued as COSV55934247; called by muse, mutect2, varscan2
- PPIG | c.1799G>A p.R600K | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.056); catalogued as COSV53646976; called by muse, mutect2, varscan2
- PPIP5K1 | c.3419C>T p.S1140L (on ENST00000396923; = p.S1115L on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); catalogued as COSV58481544; called by muse, mutect2, varscan2
- PPM1K | c.1047G>T p.W349C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55798176; called by muse, mutect2, varscan2
- PPP1R12B | c.2827G>T p.E943* | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as COSV51790946; called by muse, mutect2, varscan2
- PRDM9 | c.110A>G p.K37R | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.989); catalogued as COSV57014888; called by muse, mutect2, varscan2
- PREX2 | c.3497T>A p.F1166Y | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV55805438; called by muse, mutect2, varscan2
- PREX2 | c.4594G>A p.G1532S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286072779, COSV55807123; called by muse, mutect2, varscan2
- PRKAA2 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as COSV64807215; called by muse, mutect2, varscan2
- PRKCB | c.1872G>C p.K624N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100335005, COSV57806666; called by muse, mutect2, varscan2
- PRKG1 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.055); catalogued as COSV64815562; called by muse, mutect2, varscan2
- PRRC2A | c.6239G>A p.G2080E | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as COSV52996270; called by muse, mutect2, varscan2
- PRSS12 | c.1632-2A>T p.X544_splice | Splice Site (SNP) | VAF 20/25 reads (80%) | catalogued as COSV56611437; called by muse, mutect2, varscan2
- PRTG | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV66841380; called by muse, mutect2, varscan2
- PSG5 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 378/686 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs752397188, COSV61654780; called by muse, mutect2, varscan2
- PSMF1 | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV55676739; called by muse, varscan2
- PTPN1 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs759986577, COSV65408632; called by muse, mutect2, varscan2
- PTPN4 | c.2454G>T p.W818C | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55310740; called by muse, mutect2, varscan2
- PTPRH | c.1417A>C p.T473P | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54751032; called by muse, mutect2, varscan2
- PWP1 | c.192G>C p.Q64H | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as COSV69832587, COSV69832712; called by muse, mutect2, varscan2
- RABEP2 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as COSV62871343; called by muse, mutect2, varscan2
- RAD21 | c.153G>T p.M51I | Missense Mutation (SNP) | VAF 65/106 reads (61%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.901); catalogued as COSV52065030; called by muse, mutect2, varscan2
- RAG1 | c.2218G>T p.A740S | Missense Mutation (SNP) | VAF 52/78 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55028442; called by muse, mutect2, varscan2
- RBBP6 | c.3916C>T p.P1306S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV60509241; called by muse, mutect2, varscan2
- RBM26 | c.1169C>G p.S390C | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs761705557, COSV57401098; called by muse, mutect2, varscan2
- RBM45 | c.722G>A p.R241Q (on ENST00000616198 / NM_001365579.1; = p.R239Q on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.86); catalogued as rs750456960, COSV53722987; called by muse, mutect2, varscan2
- REG3A | c.179C>A p.S60Y | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100532523, COSV59409425; called by muse, mutect2, varscan2
- REV3L | c.7123G>A p.E2375K | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs760207701, COSV62615958; called by muse, mutect2, varscan2
- RFX3 | c.1715G>T p.W572L | Missense Mutation (SNP) | VAF 77/104 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV56526902; called by muse, mutect2, varscan2
- RGL3 | c.1976G>T p.C659F | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV66512370; called by muse, mutect2, varscan2
- RHOBTB2 | c.708del p.K237Sfs*64 | Frame Shift Del (DEL) | VAF 30/70 reads (43%) | catalogued as rs1563291444; called by mutect2, pindel, varscan2
- RILPL1 | c.672A>C p.E224D | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV61553805; called by muse, mutect2, varscan2
- RILPL1 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV61553808; called by muse, mutect2, varscan2
- RIMKLA | c.815G>T p.C272F | Missense Mutation (SNP) | VAF 153/337 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68910036; called by muse, mutect2, varscan2
- RNASE11 | c.507C>A p.C169* | Nonsense Mutation (SNP) | VAF 24/35 reads (69%) | catalogued as COSV60088528; called by muse, mutect2, varscan2
- RNF122 | c.27G>T p.G9= | Splice Region (SNP) | VAF 37/76 reads (49%) | catalogued as COSV56360324; called by muse, mutect2, varscan2
- ROBO1 | c.4909G>A p.E1637K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.039); catalogued as COSV71399400; called by muse, mutect2, varscan2
- ROBO2 | c.3308G>T p.S1103I | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV59947390; called by muse, mutect2, varscan2
- ROBO2 | c.4043T>A p.V1348E | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.023); catalogued as COSV100168128, COSV59947404; called by muse, mutect2, varscan2
- RPP30 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.867); catalogued as COSV53298409; called by muse, mutect2, varscan2
- RPS16 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52240073; called by muse, mutect2, varscan2
- RPUSD4 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 121/471 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53600553; called by muse, mutect2, varscan2
- RRAGB | c.97G>T p.V33L | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV99468994; called by muse, mutect2
- RYR2 | c.2083G>T p.V695L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63721131; called by muse, mutect2, varscan2
- RYR2 | c.4121A>G p.K1374R | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV63721139; called by muse, mutect2, varscan2
- RYR2 | c.6640A>G p.M2214V | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63721144; called by muse, mutect2
- RYR2 | c.12017C>G p.S4006C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63667318; called by muse, mutect2, varscan2
- RYR2 | c.13732C>G p.L4578V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as COSV63694114, COSV63721157; called by muse, mutect2, varscan2
- RYR3 | c.1922G>T p.S641I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66811651; called by muse, mutect2
- S100A7 | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as COSV64193842; called by muse, mutect2, varscan2
- SALL1 | c.3258G>T p.K1086N | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV51765767; called by muse, mutect2, varscan2
- SALL1 | c.2303G>T p.C768F | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51765774; called by muse, mutect2, varscan2
- SCN1A | c.1451C>G p.S484C | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs762071209, COSV57692016; called by muse, mutect2, varscan2
- SEC16A | c.1451G>C p.S484T | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); catalogued as COSV51543176; called by muse, mutect2, varscan2
- SEC23B | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as COSV52724716; called by muse, mutect2, varscan2
- SELE | c.579C>A p.C193* | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as COSV60978311; called by muse, mutect2, varscan2
- SELP | c.2163G>C p.W721C | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs745515214, COSV55259998; called by muse, mutect2, varscan2
- SEMA3A | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 79/126 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV54888544, COSV54892825; called by muse, mutect2, varscan2
- SEMA4G | c.300G>T p.M100I | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as COSV52972982; called by muse, mutect2, varscan2
- SEMA5B | c.1730G>T p.G577V | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV52110021, COSV52110955; called by muse, mutect2, varscan2
- SETD2 | c.7084C>G p.Q2362E | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV57433176, COSV57453172; called by muse, mutect2, varscan2
- SETD2 | c.3379C>G p.Q1127E | Missense Mutation (SNP) | VAF 52/78 reads (67%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); catalogued as COSV57450405; called by muse, mutect2, varscan2
- SETD2 | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 69/117 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.476); catalogued as COSV57455159; called by muse, mutect2, varscan2
- SGCD | c.256C>T p.Q86* (on ENST00000435422 / NM_001128209.2; = p.Q87* on NM_000337.5) | Nonsense Mutation (SNP) | VAF 19/30 reads (63%) | catalogued as COSV61918904; called by muse, mutect2, varscan2
- SGO2 | c.2101G>T p.V701F | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV63418712; called by muse, mutect2, varscan2
- SH3TC1 | c.1271A>T p.Q424L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.312); catalogued as COSV55291218; called by muse, mutect2, varscan2
- SHANK1 | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53265087; called by muse, mutect2, varscan2
- SHROOM2 | c.2224G>T p.G742W | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV66611441; called by mutect2, varscan2
- SI | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.087); catalogued as COSV52281894, COSV52306245; called by muse, mutect2, varscan2
- SIM1 | c.176-1G>T p.X59_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as COSV53497926; called by muse, mutect2
- SLA | c.188C>A p.S63Y (on ENST00000338087 / NM_001045556.3; = p.S103Y on NM_006748.4) | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55075545, COSV55097973; called by muse, mutect2, varscan2
- SLAMF9 | c.368A>C p.Q123P | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV63637447; called by muse, mutect2, varscan2
- SLC12A8 | c.126G>T p.W42C | Missense Mutation (SNP) | VAF 83/170 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775632819, COSV58871990; called by muse, mutect2, varscan2
- SLC35F1 | c.1096G>C p.V366L | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as COSV64505422, COSV64511492; called by muse, mutect2, varscan2
- SLC35F5 | c.142G>T p.V48L | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV55520783; called by muse, mutect2, varscan2
- SLC36A1 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as COSV54657065; called by muse, mutect2, varscan2
- SLC39A12 | c.203T>C p.L68S | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV66203162; called by muse, mutect2, varscan2
- SLC45A1 | c.1402C>A p.P468T | Missense Mutation (SNP) | VAF 59/93 reads (63%) | SIFT tolerated (0.46); PolyPhen benign (0.164); catalogued as COSV57101754; called by muse, mutect2, varscan2
- SLC4A1AP | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV58138309; called by muse, mutect2, varscan2
- SLC52A1 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs757695687, COSV54693971; called by muse, mutect2, varscan2
- SLC5A12 | c.746G>T p.W249L | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54825843; called by muse, mutect2
- SLC6A8 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 68/88 reads (77%) | SIFT tolerated (0.22); PolyPhen benign (0.141); catalogued as COSV53473846; called by muse, mutect2, varscan2
- SLC9C2 | c.2368C>A p.L790I | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV62950295; called by muse, mutect2, varscan2
- SLIT3 | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100269450, COSV60637338; called by muse, mutect2, varscan2
- SLITRK3 | c.2534G>A p.G845E | Missense Mutation (SNP) | VAF 75/187 reads (40%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.994); catalogued as rs762312693, COSV53849171, COSV53854655; called by muse, mutect2, varscan2
- SLITRK5 | c.1172T>A p.V391E | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61527424; called by muse, mutect2, varscan2
- SLITRK5 | c.1700G>C p.C567S | Missense Mutation (SNP) | VAF 87/201 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61527441; called by muse, mutect2, varscan2
- SMARCA1 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); catalogued as rs865822912, COSV64414204; called by muse, mutect2, varscan2
- SMARCA4 | c.2539C>T p.Q847* | Nonsense Mutation (SNP) | VAF 10/14 reads (71%) | catalogued as COSV60792024; called by muse, mutect2, varscan2
- SMARCAL1 | c.104G>C p.R35T | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV100620050, COSV61924357; called by muse, mutect2, varscan2
- SMC4 | c.2329A>T p.N777Y | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV61004517, COSV61008641; called by muse, mutect2, varscan2
- SNRNP200 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV60495441; called by muse, mutect2, varscan2
- SNTG1 | c.596G>T p.W199L | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV52479257; called by muse, mutect2, varscan2
- SNURF | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.561); catalogued as COSV57601445; called by muse, mutect2, varscan2
- SORCS1 | c.3457C>A p.P1153T | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.154); catalogued as COSV53913894; called by muse, mutect2, varscan2
- SP140 | c.2123G>A p.C708Y | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59456261; called by muse, mutect2, varscan2
- SPAG17 | c.4559T>C p.I1520T | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV60470662; called by muse, mutect2, varscan2
- SPATA18 | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV54651656; called by muse, mutect2, varscan2
- SPEF2 | c.2909G>C p.R970T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.077); catalogued as COSV61554571; called by muse, mutect2, varscan2
- SPEN | c.9802C>T p.R3268C | Missense Mutation (SNP) | VAF 110/140 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs200479229, COSV65361455; called by muse, mutect2, varscan2
- SPIDR | c.685A>T p.K229* | Nonsense Mutation (SNP) | VAF 37/119 reads (31%) | catalogued as COSV52393864; called by muse, mutect2, varscan2
- SPOCK1 | c.415T>G p.C139G | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56469978; called by muse, mutect2, varscan2
- SPRR1B | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); catalogued as COSV61068188; called by muse, mutect2, varscan2
- SPTA1 | c.4378C>A p.L1460I | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63761548; called by muse, mutect2, varscan2
- SPTBN5 | c.4806G>T p.Q1602H | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV58028949; called by muse, mutect2
- SRCAP | c.6751G>A p.E2251K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); catalogued as COSV52682982; called by muse, mutect2, varscan2
- SSTR4 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 45/65 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54800777; called by muse, mutect2, varscan2
- ST18 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 29/50 reads (58%) | catalogued as COSV52513199; called by muse, mutect2, varscan2
- STAG2 | c.2695A>G p.I899V | Missense Mutation (SNP) | VAF 51/63 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54375331; called by muse, mutect2, varscan2
- SULT1C2 | c.749A>T p.D250V | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52264450, COSV52267694; called by muse, mutect2
- SUPT20H | c.1342G>A p.V448M (on ENST00000350612 / NM_001014286.3; = p.V449M on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs1394904582, COSV62250081; called by muse, mutect2, varscan2
- SYNE1 | c.23461-1G>C p.X7821_splice (on ENST00000367255 / NM_182961.4; = p.X7750_splice on NM_033071.3) | Splice Site (SNP) | VAF 49/97 reads (51%) | catalogued as COSV55131634; called by muse, mutect2, varscan2
- SYNJ2BP | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs201847524, COSV56445361; called by muse, mutect2, varscan2
- TAS2R31 | c.795A>T p.K265N | Missense Mutation (SNP) | VAF 172/339 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV66831372; called by muse, mutect2, varscan2
- TBX22 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.79); catalogued as COSV64785722, COSV64788265; called by muse, mutect2, varscan2
- TCF20 | c.5783G>T p.R1928M | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59493167; called by muse, mutect2, varscan2
- TDRD3 | c.1839G>C p.W613C | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52165604; called by muse, mutect2, varscan2
- TEC | c.1678A>T p.T560S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.605); catalogued as COSV51920550; called by muse, mutect2, varscan2
- TECTA | c.4168G>T p.A1390S | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV50723773, COSV50838420; called by muse, mutect2, varscan2
- TEX13A | c.695C>A p.A232D | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV61189126; called by muse, mutect2, varscan2
- TFPI | c.401G>T p.C134F | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51906783; called by muse, mutect2, varscan2
- TIAM2 | c.2722G>C p.A908P | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV59706021; called by muse, mutect2, varscan2
- TLE4 | c.2267A>G p.Y756C | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54643237; called by muse, mutect2, varscan2
- TLR7 | c.1510A>T p.S504C | Missense Mutation (SNP) | VAF 74/122 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV66125850; called by muse, mutect2, varscan2
- TM9SF4 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as rs1433434891, COSV54104953; called by muse, mutect2, varscan2
- TMC4 | c.317G>A p.R106K (on ENST00000617472 / NM_001145303.3; = p.R100K on NM_144686.4) | Missense Mutation (SNP) | VAF 69/110 reads (63%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV55474923, COSV55477381; called by muse, mutect2, varscan2
- TMEM71 | c.794C>A p.S265* (on ENST00000523829 / NM_001382398.1; = p.S246* on NM_144649.3) | Nonsense Mutation (SNP) | VAF 21/105 reads (20%) | catalogued as COSV63458662, COSV63459863; called by muse, mutect2, varscan2
- TNC | c.4496C>G p.P1499R | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV60791940; called by muse, mutect2, varscan2
- TNC | c.3478G>T p.A1160S | Missense Mutation (SNP) | VAF 151/222 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV60791944; called by muse, mutect2, varscan2
- TNR | c.861C>A p.Y287* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV54880995, COSV54919396; called by muse, mutect2, varscan2
- TNS1 | c.2752G>T p.V918F | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs758924814, COSV50787497; called by muse, mutect2, varscan2
- TOLLIP | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55138706; called by muse, mutect2, varscan2
- TP53BP1 | c.1780A>G p.R594G | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.118); catalogued as COSV55511494; called by muse, mutect2, varscan2
- TP53I13 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.01); catalogued as COSV56196946; called by muse, mutect2, varscan2
- TPR | c.2896C>G p.Q966E | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV66606125; called by muse, mutect2, varscan2
- TRAF1 | c.987G>C p.M329I | Missense Mutation (SNP) | VAF 78/324 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV65869660; called by muse, mutect2, varscan2
- TRAK2 | c.1561G>T p.V521F | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV60275892; called by muse, mutect2, varscan2
- TRIAP1 | c.53G>C p.C18S | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56664328; called by muse, mutect2, varscan2
- TRIM44 | c.949C>G p.L317V | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV54988415; called by muse, mutect2, varscan2
- TRIM68 | c.199A>T p.R67W | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs991127490, COSV56170493; called by muse, mutect2, varscan2
- TRIP12 | c.2425A>T p.S809C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV52274419; called by muse, mutect2, varscan2
- TRMT9B | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV71600874; called by muse, mutect2, varscan2
- TRPC7 | c.1894G>T p.E632* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100725409, COSV61462273; called by muse, mutect2
- TRPM3 | c.2067G>C p.M689I (on ENST00000357533 / NM_001366142.2; = p.M532I on NM_020952.6) | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV62596871; called by muse, mutect2, varscan2
- TRPM5 | c.1922T>C p.M641T | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs758446869, COSV50217112; called by muse, mutect2, varscan2
- TSHR | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as CM077986, COSV53334461; called by muse, mutect2, varscan2
- TTC16 | c.1020C>A p.H340Q | Missense Mutation (SNP) | VAF 49/60 reads (82%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV64781063; called by muse, mutect2, varscan2
- TTN | c.50843G>C p.G16948A (on ENST00000591111; = p.G9524A on NM_003319.4) | Missense Mutation (SNP) | VAF 42/71 reads (59%) | PolyPhen possibly damaging (0.819); catalogued as COSV60417840; called by muse, mutect2, varscan2
- TTN | c.44581A>G p.K14861E (on ENST00000591111; = p.K7437E on NM_003319.4) | Missense Mutation (SNP) | VAF 79/199 reads (40%) | PolyPhen probably damaging (0.994); catalogued as COSV60417869; called by muse, mutect2, varscan2
- TTN | c.24941C>A p.A8314D (on ENST00000591111; = p.A7387D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/69 reads (58%) | PolyPhen benign (0.006); catalogued as COSV60417906; called by muse, mutect2, varscan2
- TTN | c.15720G>T p.K5240N (on ENST00000591111; = p.K4313N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/146 reads (56%) | PolyPhen benign (0.003); catalogued as COSV60417965; called by muse, mutect2, varscan2
- TUBA3D | c.828C>G p.I276M | Missense Mutation (SNP) | VAF 120/233 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.404); catalogued as COSV58313670; called by muse, mutect2, varscan2
- TUT1 | c.122G>C p.R41P | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as COSV53472508, COSV53472623; called by muse, mutect2, varscan2
- TUT4 | c.3535G>C p.G1179R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV57120852; called by muse, mutect2
- TXK | c.1309G>C p.V437L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51920540; called by muse, mutect2, varscan2
- U2SURP | c.821C>A p.T274N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101204316; called by muse, mutect2
- UBAP2L | c.3164G>A p.G1055D | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55176708, COSV55183191; called by muse, mutect2, varscan2
- UBR3 | c.3739G>C p.E1247Q | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV55863301; called by muse, mutect2, varscan2
- UGDH | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57100359; called by muse, mutect2, varscan2
- UGT1A6 | c.101A>T p.Q34L | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV59401223; called by muse, mutect2, varscan2
- UGT2A2 | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.736); catalogued as COSV99683758; called by muse, mutect2, varscan2
- UGT2A2 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV99683760; called by muse, mutect2, varscan2
- UGT2B4 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59321460; called by muse, mutect2, varscan2
- UMODL1 | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV68554971, COSV68558297; called by muse, mutect2, varscan2
- UNC5A | c.1669C>A p.H557N | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV52846100; called by muse, mutect2, varscan2
- UNC5CL | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as rs757538729, COSV55112548; called by muse, mutect2, varscan2
- UNC5D | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54844670; called by muse, mutect2, varscan2
- UNC79 | c.1412G>T p.R471L (on ENST00000393151 / NM_001346218.2; = p.R294L on NM_020818.5) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.736); catalogued as COSV56396762, COSV99825496; called by muse, mutect2, varscan2
- UNC79 | c.6404T>A p.L2135Q (on ENST00000393151 / NM_001346218.2; = p.L1958Q on NM_020818.5) | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56417352; called by muse, mutect2, varscan2
- UNC79 | c.6808C>A p.L2270I (on ENST00000393151 / NM_001346218.2; = p.L2093I on NM_020818.5) | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.74); catalogued as COSV56417377; called by muse, mutect2, varscan2
- UNKL | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV57021693; called by muse, mutect2, varscan2
- UPF3A | c.932A>C p.K311T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV60896453; called by muse, mutect2, varscan2
- USH2A | c.92C>G p.T31S | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100228269, COSV56335742; called by muse, mutect2, varscan2
- USP29 | c.2134A>G p.T712A | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV54147538; called by muse, mutect2, varscan2
- USP45 | c.47G>T p.R16I | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57329337, COSV57330668, COSV57330843; called by muse, mutect2, varscan2
- VANGL2 | c.109G>T p.G37W | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV63605661; called by muse, mutect2, varscan2
- VANGL2 | c.395T>A p.L132Q | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV63605665; called by muse, mutect2, varscan2
- VEGFC | c.1172G>T p.R391L | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as rs201028890, COSV54608824; called by muse, mutect2, varscan2
- VIRMA | c.3149C>T p.S1050L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV52592556; called by muse, mutect2, varscan2
- WARS2 | c.995A>T p.E332V | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as COSV52477253, COSV99345845; called by muse, mutect2, varscan2
- WARS2 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as COSV99345849; called by muse, mutect2, varscan2
- WASF3 | c.283A>T p.I95F | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV58973066; called by muse, mutect2, varscan2
- WDPCP | c.1119A>T p.L373F | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as rs755766939, COSV55435377; called by muse, mutect2, varscan2
- WDR19 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV56471068; called by muse, mutect2, varscan2
- WDR59 | c.2401A>T p.T801S | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV50947682; called by muse, mutect2, varscan2
- WSCD2 | c.498-1G>T p.X166_splice | Splice Site (SNP) | VAF 15/55 reads (27%) | catalogued as COSV54592574; called by muse, mutect2, varscan2
- XIRP2 | c.347G>T p.S116I (on ENST00000628543; = p.S291I on NM_152381.6) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as COSV54741102, COSV99745210; called by muse, mutect2
- XIRP2 | c.8429G>C p.G2810A (on ENST00000628543; = p.G2985A on NM_152381.6) | Missense Mutation (SNP) | VAF 74/135 reads (55%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs892476743, COSV54692762, COSV54741122; called by muse, mutect2, varscan2
- YY1AP1 | c.1736G>T p.R579I (on ENST00000295566 / NM_139118.2; = p.R522I on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV55125406, COSV99804348; called by muse, mutect2, varscan2
- ZFHX4 | c.1847C>A p.P616Q | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50483727; called by muse, mutect2, varscan2
- ZFPM2 | c.984C>G p.F328L | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV65874556, COSV65876569; called by muse, mutect2, varscan2
- ZKSCAN7 | c.931A>G p.T311A | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200722624, COSV56275019; called by muse, mutect2, varscan2
- ZNF100 | c.1155del p.S386Hfs*64 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as COSV99974088; called by mutect2, pindel, varscan2
- ZNF208 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as COSV68114009; called by muse, mutect2, varscan2
- ZNF347 | c.90G>T p.R30S | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV61971456; called by muse, mutect2, varscan2
- ZNF365 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV67926755; called by muse, mutect2, varscan2
- ZNF385B | c.152G>T p.C51F | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69808780; called by muse, mutect2, varscan2
- ZNF483 | c.1885C>T p.H629Y | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58517514; called by muse, varscan2
- ZNF483 | c.1960C>G p.Q654E | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV58517519; called by muse, varscan2
- ZNF551 | c.1978C>T p.R660* | Nonsense Mutation (SNP) | VAF 67/206 reads (33%) | catalogued as rs547649876, COSV56594567; called by muse, mutect2, varscan2
- ZNF585B | c.1903del p.V635Cfs*43 | Frame Shift Del (DEL) | VAF 36/135 reads (27%) | catalogued as COSV100459343; called by mutect2, varscan2
- ZWINT | c.265G>C p.A89P | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV59186573; called by muse, mutect2, varscan2
- AGO3 | c.2153G>T p.C718F | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ARHGAP18 | c.203_206delinsTTT p.D68Vfs*13 | Frame Shift Del (DEL) | VAF 24/126 reads (19%) | called by pindel, varscan2*
- ARHGEF7 | c.2386del p.C796Afs*16 (on ENST00000375741 / NM_001113511.2; = p.C775Afs*16 on NM_145735.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/103 reads (33%) | called by mutect2, pindel, varscan2
- DNAJA2 | c.706del p.E236Kfs*34 | Frame Shift Del (DEL) | VAF 28/144 reads (19%) | called by mutect2, pindel, varscan2
- FMR1 | c.594_596del p.I199del | In Frame Del (DEL) | VAF 20/107 reads (19%) | called by mutect2, pindel, varscan2
- HS6ST1 | c.238C>A p.R80S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.013); called by muse, mutect2
- IGKV1D-17 | c.28del p.L10Wfs*17 | Frame Shift Del (DEL) | VAF 36/98 reads (37%) | called by mutect2, varscan2
- KARS1 | c.333dup p.Y112Ifs*2 | Frame Shift Ins (INS) | VAF 85/210 reads (40%) | called by mutect2, pindel, varscan2
- KBTBD12 | c.1721dup p.L574Ffs*21 | Frame Shift Ins (INS) | VAF 23/115 reads (20%) | called by mutect2, pindel, varscan2
- MLLT6 | c.58A>T p.N20Y | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLCL1 | c.2750dup p.P919Sfs*20 | Frame Shift Ins (INS) | VAF 146/506 reads (29%) | called by pindel, varscan2
- PRAG1 | c.3712del p.R1238Gfs*120 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | called by mutect2, pindel, varscan2
- RFC1 | c.675del p.F225Lfs*5 | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | called by mutect2, pindel, varscan2
- SYNE1 | c.4024dup p.W1342Lfs*5 (on ENST00000367255 / NM_182961.4; = p.W1349Lfs*5 on NM_033071.3) | Frame Shift Ins (INS) | VAF 7/19 reads (37%) | called by mutect2, pindel, varscan2
- TPO | c.1876_1878delinsAA p.Y626Kfs*14 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | called by pindel, varscan2*
- ZNF135 | c.999dup p.A334Sfs*25 (on ENST00000313434 / NM_001289401.2; = p.A346Sfs*25 on NM_003436.4) | Frame Shift Ins (INS) | VAF 31/67 reads (46%) | called by mutect2, pindel, varscan2
- ZNF677 | c.1197del p.E400Rfs*213 | Frame Shift Del (DEL) | VAF 19/113 reads (17%) | called by mutect2, pindel, varscan2
- ZNF780B | c.75dup p.D26* | Frame Shift Ins (INS) | VAF 52/239 reads (22%) | called by mutect2, pindel, varscan2
- ABCA4 | c.6045C>A p.G2015= | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as COSV64679591; called by muse, mutect2, varscan2
- ABLIM1 | c.1836A>T p.S612= | Silent (SNP) | VAF 48/113 reads (42%) | catalogued as COSV53318105; called by muse, mutect2, varscan2
- ACAD10 | c.2218C>T p.L740= | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as COSV58164614; called by muse, mutect2, varscan2
- ACSS2 | c.1530T>A p.G510= | Silent (SNP) | VAF 184/436 reads (42%) | catalogued as COSV53629025; called by muse, mutect2, varscan2
- ADCY4 | c.609C>T p.F203= | Silent (SNP) | VAF 21/31 reads (68%) | catalogued as COSV53477997; called by muse, mutect2, varscan2
- ADD3 | c.426C>T p.A142= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs1214905648, COSV53326837; called by muse, mutect2, varscan2
- ADGRL2 | c.954C>T p.C318= | Silent (SNP) | VAF 61/110 reads (55%) | catalogued as rs1482824559, COSV54692418, COSV54694475; called by muse, mutect2, varscan2
- AGAP6 | c.849C>T p.T283= (on ENST00000374056 / NM_001365867.1; = p.T306= on NM_001077665.2) | Silent (SNP) | VAF 144/432 reads (33%) | catalogued as COSV65018636; called by muse, varscan2
- AHNAK | c.4275G>A p.V1425= | Silent (SNP) | VAF 150/414 reads (36%) | catalogued as COSV57235340; called by muse, mutect2, varscan2
- ARHGAP9 | c.660G>A p.E220= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as rs61740924, COSV62724760; called by muse, mutect2, varscan2
- ARHGEF12 | c.1165T>C p.L389= | Silent (SNP) | VAF 76/175 reads (43%) | catalogued as COSV63108052; called by muse, mutect2, varscan2
- ASB4 | c.48A>G p.L16= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as COSV57509269; called by muse, mutect2, varscan2
- ASXL1 | c.2265G>T p.G755= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV60125359; called by muse, mutect2
- BIRC6 | c.10203G>C p.L3401= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV70207671; called by muse, mutect2, varscan2
- BPIFB6 | c.651C>T p.Y217= | Silent (SNP) | VAF 83/205 reads (40%) | catalogued as rs962826114, COSV62757010; called by muse, mutect2, varscan2
- C10orf120 | c.156G>C p.L52= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV61492889; called by muse, mutect2, varscan2
- CEMIP2 | c.1854C>T p.F618= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV65490144; called by muse, mutect2, varscan2
- CNGB1 | c.1545G>A p.L515= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV51908448; called by muse, mutect2, varscan2
- CNTN2 | c.576G>A p.L192= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs1232729829, COSV59351277; called by muse, mutect2, varscan2
- COL2A1 | c.1884G>C p.L628= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV61535494; called by muse, varscan2
- COPB2 | c.831G>T p.V277= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV100300429; called by muse, mutect2, varscan2
- COPG1 | c.210C>T p.F70= | Silent (SNP) | VAF 56/100 reads (56%) | catalogued as COSV59114096; called by muse, mutect2, varscan2
- CRB1 | c.3117T>A p.L1039= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as COSV66334804; called by muse, mutect2, varscan2
- CRB2 | c.906G>T p.A302= | Silent (SNP) | VAF 24/33 reads (73%) | catalogued as COSV63506044; called by muse, mutect2, varscan2
- CSPG4 | c.3429C>A p.G1143= | Silent (SNP) | VAF 56/144 reads (39%) | catalogued as COSV57902940; called by muse, mutect2, varscan2
- CYP4F8 | c.1239C>A p.V413= | Silent (SNP) | VAF 54/80 reads (68%) | catalogued as COSV57855803; called by muse, mutect2, varscan2
- DCAF5 | c.1180C>T p.L394= | Silent (SNP) | VAF 51/195 reads (26%) | catalogued as COSV58463785; called by muse, mutect2, varscan2
- DCPS | c.381A>G p.V127= | Silent (SNP) | VAF 52/248 reads (21%) | catalogued as rs773592034, COSV55012708; called by muse, varscan2
- DCPS | c.408A>T p.T136= | Silent (SNP) | VAF 52/227 reads (23%) | catalogued as COSV55012721; called by muse, varscan2
- DEPDC1B | c.1155G>A p.L385= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV54013816; called by muse, mutect2, varscan2
- DEPDC4 | c.6G>C p.V2= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as COSV54554646; called by muse, mutect2, varscan2
- DGKD | c.564G>C p.T188= (on ENST00000264057 / NM_152879.3; = p.T144= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/161 reads (24%) | catalogued as COSV51121250; called by muse, mutect2, varscan2
- DHX37 | c.1107G>A p.V369= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV58140452; called by muse, mutect2
- DNAJB13 | c.234G>A p.L78= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as rs1565171648, COSV60271406; called by muse, mutect2, varscan2
- DNTT | c.765A>T p.V255= | Silent (SNP) | VAF 63/145 reads (43%) | catalogued as COSV64523863; called by muse, mutect2, varscan2
- EDAR | c.1323C>T p.A441= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV51508854; called by muse, mutect2, varscan2
- EFHC2 | c.1251G>A p.R417= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV69556008; called by muse, mutect2, varscan2
- ERAS | c.309G>A p.R103= | Silent (SNP) | VAF 43/66 reads (65%) | catalogued as COSV54433360; called by muse, mutect2, varscan2
- EYA1 | c.1749G>T p.L583= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV58176361; called by muse, mutect2, varscan2
- F11R | c.495C>G p.T165= | Silent (SNP) | VAF 46/137 reads (34%) | catalogued as COSV57039681, COSV57041343; called by muse, mutect2, varscan2
- FAAH2 | c.318G>A p.K106= | Silent (SNP) | VAF 26/31 reads (84%) | catalogued as rs1188071570, COSV66512969; called by muse, mutect2, varscan2
- FADS6 | c.786C>T p.I262= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs535361532, COSV59604103; called by muse, mutect2, varscan2
- FAM153B | c.577C>T p.L193= (on ENST00000253490; = p.L116= on NM_001265615.1) | Silent (SNP) | VAF 69/237 reads (29%) | catalogued as COSV53689159; called by muse, mutect2, varscan2
- FAM189A2 | c.1176A>T p.T392= | Silent (SNP) | VAF 39/58 reads (67%) | catalogued as rs1460873213, COSV57386632; called by muse, mutect2, varscan2
- FAT3 | c.9303G>A p.L3101= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as COSV53188495; called by muse, mutect2
- FAT4 | c.13368A>G p.P4456= | Silent (SNP) | VAF 35/48 reads (73%) | catalogued as COSV58713975; called by muse, mutect2, varscan2
- FCAMR | c.570G>T p.P190= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as COSV61370084; called by muse, varscan2
- FGD4 | c.564G>A p.L188= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV99846731; called by muse, mutect2, varscan2
- FGFR1 | c.1113G>T p.S371= (on ENST00000447712 / NM_023110.3; = p.S369= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs763302356, COSV58327390, COSV58346598; called by muse, mutect2, varscan2
- FMR1NB | c.63G>T p.V21= | Silent (SNP) | VAF 42/62 reads (68%) | catalogued as COSV65072481; called by muse, mutect2, varscan2
- FNBP4 | c.957A>G p.K319= | Silent (SNP) | VAF 39/56 reads (70%) | catalogued as COSV55452994; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.87C>A p.T29= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100598430; called by muse, mutect2
- FRG1 | c.588A>G p.E196= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99902267; called by muse, mutect2, varscan2
- FZD1 | c.1200G>A p.E400= | Silent (SNP) | VAF 41/63 reads (65%) | catalogued as rs1168321048, COSV55313892; called by muse, mutect2, varscan2
- GABPB2 | c.711C>T p.P237= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV64461730; called by muse, mutect2
- GALNT8 | c.627C>T p.P209= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV52902454, COSV52902803; called by muse, mutect2, varscan2
- GATA2 | c.1302T>A p.A434= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV62007925; called by muse, mutect2, varscan2
- GCN1 | c.3399C>G p.V1133= | Silent (SNP) | VAF 70/138 reads (51%) | catalogued as COSV56116207; called by muse, mutect2, varscan2
- GLB1L | c.519C>T p.H173= | Silent (SNP) | VAF 69/147 reads (47%) | catalogued as rs780736846, COSV55479639; called by muse, mutect2, varscan2
- GLI2 | c.3489T>C p.F1163= (on ENST00000361492 / NM_001374353.1; = p.F1180= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as rs766031476, COSV58053496; called by muse, mutect2, varscan2
- GPC6 | c.1365G>C p.R455= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as COSV65543285; called by muse, mutect2, varscan2
- GPR132 | c.291C>A p.L97= | Silent (SNP) | VAF 28/164 reads (17%) | catalogued as COSV61678501; called by muse, mutect2, varscan2
- GPR4 | c.375C>T p.F125= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as rs144692714; called by muse, mutect2, varscan2
- GRIK2 | c.2340A>T p.I780= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs775302271, COSV59781019; called by muse, mutect2, varscan2
- GRM5 | c.1599C>A p.T533= | Silent (SNP) | VAF 46/104 reads (44%) | catalogued as COSV59635020; called by muse, mutect2, varscan2
- GTF3C1 | c.729A>G p.L243= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as COSV62245803; called by muse, mutect2, varscan2
- GUK1 | c.348G>T p.R116= | Silent (SNP) | VAF 71/151 reads (47%) | catalogued as COSV57158612; called by muse, mutect2, varscan2
- HBB | c.369C>T p.F123= | Silent (SNP) | VAF 52/76 reads (68%) | catalogued as rs33973589, COSV58943386; called by muse, mutect2, varscan2
- HCN1 | c.2527C>A p.R843= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as COSV57504666, COSV57542388; called by muse, mutect2, varscan2
- HEPHL1 | c.555G>T p.V185= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as COSV100244439, COSV59897799; called by muse, mutect2, varscan2
- HOXB9 | c.504G>A p.E168= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as COSV60817955; called by muse, mutect2, varscan2
- HTR2B | c.1254G>A p.R418= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV51450940; called by muse, mutect2, varscan2
- HYAL1 | c.1143C>T p.L381= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV56499711; called by muse, mutect2, varscan2
- IL7R | c.570C>A p.L190= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV57414807; called by muse, mutect2, varscan2
- ING1 | c.1059C>G p.P353= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV58172538; called by muse, varscan2
- ING4 | c.12G>C p.G4= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs774132579, COSV58556814; called by muse, mutect2, varscan2
- IQSEC3 | c.2838C>A p.T946= (on ENST00000538872 / NM_001170738.2; = p.T643= on NM_015232.1) | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV58292421; called by muse, mutect2, varscan2
- IRAK3 | c.783A>G p.P261= | Silent (SNP) | VAF 72/184 reads (39%) | catalogued as COSV54166775; called by muse, mutect2, varscan2
- ITGAE | c.1425C>T p.S475= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV53995352, COSV54001595, COSV99561609; called by muse, mutect2, varscan2
- ITGB4 | c.4329G>A p.V1443= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV52334530; called by muse, mutect2, varscan2
- KCNAB1 | c.105C>A p.P35= | Silent (SNP) | VAF 53/126 reads (42%) | catalogued as COSV67491429; called by muse, mutect2, varscan2
- KCNJ10 | c.627T>A p.I209= | Silent (SNP) | VAF 51/96 reads (53%) | catalogued as COSV63635297; called by muse, mutect2, varscan2
- KDM2A | c.207G>T p.R69= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV67084323; called by muse, mutect2, varscan2
- KIAA0232 | c.1869C>G p.L623= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV56930190; called by muse, mutect2, varscan2
- KIF2B | c.1920G>T p.R640= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as COSV52136815; called by muse, mutect2, varscan2
- KIR3DL2 | c.105C>A p.P35= | Silent (SNP) | VAF 144/219 reads (66%) | called by muse, mutect2, varscan2
- KRI1 | c.888G>A p.Q296= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV57266145; called by muse, mutect2, varscan2
117 further variants in this file (0 protein-altering or splice-affecting, 100 silent, 17 other) are not listed here.
